Gene-level copy-number profile of tumor specimen ALCH-B2FI-TTP1-A from ALCHEMIST case ALCH-B2FI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,113 days).
Specimen ALCH-B2FI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 604f90f6-3ab8-43c7-a241-dd919a9888f5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2FI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/7efb5518-1a69-454b-9b94-ed9baa0253a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 12,328; copy number 2: 38,340; copy number 3: 5,363; copy number 4: 2,033; copy number 5: 118; copy number 6: 26; copy number 7: 1; copy number 8: 120; copy number 22: 28.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:25,176,832–25,250,940, 41 genes (within-gene range 0–1): SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr19:23,015,059–23,063,705, 2 genes: LINC01859, LINC01858.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 293 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,117,163–111,185,104, 2 genes, copy number 5 (within-gene range 3–5): DRAM2, CEPT1.
- chr2:102,064,544–102,179,874, 1 gene, copy number 5 (within-gene range 4–5): IL1R1.
- chr3:195,836,193–198,123,232, 92 genes, copy number 5 (broad region; genes not listed).
- chr7:52,891,837–57,275,197, 128 genes, copy number 6–22 (broad region; genes not listed).
- chr7:104,940,943–105,115,019, 4 genes, copy number 5 (within-gene range 2–5): AC007384.1, LINC01004, KMT2E-AS1, KMT2E.
- chr12:12,715,058–12,724,011, 3 genes, copy number 5: CDKN1B, AC008115.3, AC008115.1.
- chr15:85,380,571–85,749,358, 10 genes, copy number 5 (within-gene range 2–5): AKAP13, MIR7706, RNU7-79P, FABP5P9, AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3.
- chr18:30,713,275–32,470,882, 49 genes, copy number 5–8: AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1, DSG1-AS1, RNU6-167P, DSG4, Y_RNA, DSG3, AC021549.1, DSG2, DSG2-AS1, TTR, B4GALT6, AC017100.1, RN7SKP44, LRRC37A7P, AC017100.2, SLC25A52, TRAPPC8, AC022960.1, AC022960.3, AC022960.2, RNU6-1050P, AC009831.1, PGDP1, AC009831.2, AC009831.4, RNF125, AC011825.3, AC009831.3, AC011825.1, AC011825.4, RNF138, AC011825.2, GAREM1, RNA5SP453, MEP1B, CLUHP6, AC015563.1, Y_RNA, AC015563.2, HNRNPA1P7.
- chr21:43,414,483–43,479,534, 4 genes, copy number 6–8: SIK1, LINC00319, LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 9,984. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
